Somatic mutation profile of tumor specimen 0DRGEY from CCDI case PBCGBM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.9 years (682 days).
Specimen 0DRGEY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3638c0f1-f4ea-4134-9ab0-d06564853494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGEH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29fb0a53-4e63-426b-b325-3d17ffa196c9

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 2, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNG2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 132/516 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430487866; called by muse, mutect2, varscan2
- KMT2D | c.11635_11636del p.L3880Dfs*131 | Frame Shift Del (DEL) | VAF 162/498 reads (33%) | catalogued as rs1555188561; called by pindel, varscan2
- KMT2D | c.4472G>A p.W1491* | Nonsense Mutation (SNP) | VAF 277/669 reads (41%) | catalogued as COSV56474120; called by muse, mutect2, varscan2
- LAX1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 215/719 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as rs778286533, COSV65849185; called by muse, mutect2, varscan2
- SEMA6B | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs962516138; called by muse, mutect2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 39/856 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- RETREG3 | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 24/802 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDK11A | c.1734T>G p.P578= (on ENST00000378633 / NM_001313896.2; = p.P575= on NM_024011.4) | Silent (SNP) | VAF 37/491 reads (8%) | called by muse, mutect2
- KMT2C | c.12306C>T p.S4102= | Silent (SNP) | VAF 231/554 reads (42%) | called by muse, mutect2, varscan2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 37/917 reads (4%) | catalogued as COSV57072566; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 41/689 reads (6%) | called by muse, mutect2
- DYRK1A | c.-18G>A | 5'UTR (SNP) | VAF 271/672 reads (40%) | catalogued as rs1338470527; called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 28/304 reads (9%) | called by muse, varscan2
- TCOF1 | c.2859+89T>C | Intron (SNP) | VAF 10/165 reads (6%) | catalogued as rs1219055826, COSV60353458; called by muse, mutect2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 24/665 reads (4%) | called by muse, mutect2
- UFSP2 | c.*407_*408insCTTTTTAAAAAAAAGTTTTTAATG | 3'UTR (INS) | VAF 7/396 reads (2%) | called by muse*, mutect2
